Gene-level copy-number profile of tumor specimen ALCH-B2OK-TTP1-A from ALCHEMIST case ALCH-B2OK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.7 years (23,632 days).
Specimen ALCH-B2OK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0ece828e-f3ff-41fc-a3cd-24cf9f7310d7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2OK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/73f75056-6a23-45f7-8cbb-42a34a4575e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 586; copy number 1: 7,354; copy number 2: 48,222; copy number 3: 1,882; copy number 4: 451; copy number 5: 194; copy number 6: 90; copy number 7: 18; copy number 9: 100; copy number 15: 5.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,061,160–156,082,465, 2 genes: RAB25, MEX3A.
- chr2:20,239,892–20,241,046, 1 gene: DRG1P1.
- chr2:222,671,658–222,709,930, 3 genes: MOGAT1, RRAS2P2, AC104772.1.
- chr7:983,181–989,640, 1 gene: CYP2W1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:127,447,674–127,451,406, 2 genes: RPL12, SNORA65.
- chr9:128,392,007–128,393,510, 3 genes (within-gene range 0–1): AL359091.1, MIR219A2, MIR219B.
- chr9:129,834,698–129,884,170, 3 genes (within-gene range 0–4): USP20, MIR6855, AL158207.1.
- chr9:131,240,687–131,241,724, 1 gene: AL157938.1.
- chr9:136,107,808–136,109,424, 1 gene: LINC02846.
- chr9:137,255,327–137,287,236, 3 genes: NELFB, TOR4A, BX255925.2.
- chr10:101,578,882–101,588,270, 1 gene (within-gene range 0–2): POLL.
- chr10:117,128,521–117,138,301, 1 gene: VAX1.
- chr15:25,172,635–25,178,819, 4 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5.
- chr15:25,187,536–25,213,729, 15 genes (within-gene range 0–2): SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24.
- chr15:74,311,516–74,319,688, 1 gene (within-gene range 0–2): AC023300.2.
- chr15:85,770,496–85,771,163, 2 genes (within-gene range 0–2): MIR1276, AC021739.1.
- chr16:31,214,091–31,231,537, 2 genes: TRIM72, PYDC1.
- chr17:7,259,903–7,266,166, 2 genes (within-gene range 0–2): CLDN7, Y_RNA.
- chr17:7,312,661–7,329,393, 2 genes (within-gene range 0–1): AC026954.2, NEURL4.
- chr19:2,321,520–2,328,611, 1 gene (within-gene range 0–1): LSM7.
- chr19:5,978,403–6,020,363, 1 gene (within-gene range 0–1): AC011444.1.
- chr19:15,468,645–15,498,956, 1 gene: PGLYRP2.
- chr19:19,645,198–19,663,676, 1 gene: ATP13A1.
- chr19:46,390,515–46,413,564, 2 genes (within-gene range 0–2): AC007193.3, CCDC8.
- chr20:31,637,912–31,645,006, 1 gene: COX4I2.
- chr22:18,527,802–18,530,573, 1 gene: TMEM191B.
- chr22:18,605,355–18,625,289, 5 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.
- chr22:21,290,760–21,325,042, 3 genes (within-gene range 0–4): BCRP6, FAM230H, AP000552.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 404 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–180,970,762, 2 genes, copy number 5: AC091874.2, AC091874.1.
- chr6:41,026,895–44,553,281, 143 genes, copy number 6–9 (broad region; genes not listed).
- chr7:74,650,231–74,851,551, 5 genes, copy number 6: GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2.
- chr7:86,643,914–88,756,725, 34 genes, copy number 5: GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1.
- chr7:90,335,223–90,513,402, 4 genes, copy number 5 (within-gene range 4–5): GTPBP10, AC002064.3, CLDN12, AC006153.1.
- chr7:90,469,639–90,513,397, 1 gene, copy number 5 (within-gene range 4–5): AC002456.2.
- chr7:97,732,084–97,740,472, 1 gene, copy number 5: TAC1.
- chr7:129,434,432–129,757,082, 6 genes, copy number 5 (within-gene range 1–5): STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1, NRF1.
- chr7:139,133,744–139,315,394, 7 genes, copy number 5: TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P.
- chr7:141,074,064–141,480,380, 1 gene, copy number 5 (within-gene range 1–5): TMEM178B.
- chr7:141,351,977–142,451,448, 58 genes, copy number 5: NDUFB10P2, AC005692.3, AC005692.1, AC005692.2, AC073878.1, AC073878.2, AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3, TAS2R4, TAS2R6P, TAS2R5, MTCO1P55, MTND2P5, MTND1P3, MYL6P4, PRSS37, OR9A3P, OR9A1P, MGAM, OR9N1P, OR9A4, CLEC5A, TAS2R38, MGAM2, MOXD2P, PRSS58, TRY2P, AC245088.1, PRSS3P3, TRBV1, TRBV2, TRBV3-1, TRBV4-1, TRBV5-1, TRBV6-1, TRBV7-1, TRBV4-2, TRBV8-1, TRBV5-2, TRBV6-4, TRBV7-3, TRBV8-2, TRBV5-3, TRBV9, TRBV10-1, TRBV11-1, TRBV12-1, TRBV10-2, TRBV11-2, TRBV12-2, TRBV6-5.
- chr8:64,570,913–64,581,921, 2 genes, copy number 5 (within-gene range 4–5): AC090136.2, AC090136.3.
- chr12:68,248,242–70,543,040, 58 genes, copy number 7–15 (within-gene range 2–15): IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1.
- chr14:105,093,609–105,100,131, 2 genes, copy number 5: LINC02298, AL512356.4.
- chr20:56,667,430–59,516,039, 72 genes, copy number 5 (broad region; genes not listed).
- chr21:43,140,523–43,162,277, 2 genes, copy number 5–9: FRGCA, AP001631.1.
- chr22:18,400,407–18,524,935, 6 genes, copy number 9: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 5,077. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
